FM case AD707 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/9e084455-7a41-4be5-ba43-0f56eaed4626

Male, 74.4 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the esophagus; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
